Somatic mutation profile of tumor specimen TARGET-20-PARLUS-03A (aliquot TARGET-20-PARLUS-03A-01D) from TARGET case TARGET-20-PARLUS, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.1 years (5,142 days).
Specimen TARGET-20-PARLUS-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e81ff15-a7b5-4740-a430-a72eb40f3424.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARLUS-14A (Bone Marrow Normal), aliquot TARGET-20-PARLUS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a21fe68c-ecf4-40b3-81e2-a37cfb5f0626

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 53/123 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
